Somatic mutation profile of tumor specimen TCGA-LN-A9FR-01A (aliquot TCGA-LN-A9FR-01A-11D-A387-09) from TCGA case TCGA-LN-A9FR, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 70.2 years (25,657 days).
Specimen TCGA-LN-A9FR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e77374f1-cccd-44e0-a5ef-0734387d1f56.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LN-A9FR-10A (Blood Derived Normal), aliquot TCGA-LN-A9FR-10A-01D-A38A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8956dab8-d535-4aa1-a2aa-88d55919e706

The open-access MAF lists 69 somatic variants for this specimen: 56 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 11, Nonsense Mutation 2, Splice Site 2, RNA 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NOTCH1 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 10/22 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1064795070, COSV53025487, COSV53045576; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.560-1G>C p.X187_splice | Splice Site (SNP) | VAF 5/24 reads (21%) | hotspot (GDC flag); catalogued as rs1202793339, CD043957, CS011574, CS083991, COSV52662318, COSV52676510, COSV52683087, COSV52690533; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AQR | c.2764C>A p.P922T | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as COSV50031719, COSV50045080; called by muse, mutect2, varscan2
- CD1C | c.569T>C p.L190S | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.108); catalogued as COSV63807555; called by muse, mutect2, varscan2
- DDC | c.956G>T p.R319I | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.642); catalogued as COSV63564269; called by muse, mutect2, varscan2
- DPP10 | c.1598C>T p.P533L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV59690005; called by muse, mutect2, varscan2
- GCLC | c.820A>G p.I274V (on ENST00000643939; = p.I272V on NM_001498.4) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as rs1185317257; called by muse, mutect2, varscan2
- H3C13 | c.153G>C p.E51D | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.022); catalogued as COSV100516095; called by muse, mutect2, varscan2
- H4C8 | c.155A>G p.Y52C | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751532587, COSV56804750; called by muse, mutect2
- KDR | c.2350A>G p.I784V | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs749701671; called by muse, mutect2, varscan2
- KIF26B | c.3850G>A p.E1284K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs1340070459; called by muse, mutect2, varscan2
- MEIS1 | c.779C>T p.T260I | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.17); catalogued as COSV55486544; called by muse, mutect2
- MGAT5B | c.1303G>A p.D435N | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56927596; called by muse, mutect2, varscan2
- MORC1 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.76); PolyPhen benign (0.059); catalogued as rs1006439830; called by muse, mutect2, varscan2
- OSBP | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs770463074; called by muse, mutect2, varscan2
- PCDHA7 | c.1504C>A p.R502S | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as COSV65347593; called by muse, mutect2, varscan2
- PEAK1 | c.1327G>A p.V443I | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs1414078312; called by muse, mutect2, varscan2
- PLCE1 | c.1315G>T p.G439C | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.72); catalogued as COSV53356872; called by muse, mutect2, varscan2
- PLEKHA5 | c.383A>G p.Y128C | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775722790; called by muse, mutect2, varscan2
- PRSS22 | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs753423446, COSV50721039, COSV50723117; called by muse, mutect2, varscan2
- SLC6A12 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.704); catalogued as rs373249721, COSV100675235; called by mutect2, varscan2
- SPG21 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.64); PolyPhen benign (0.171); catalogued as rs587777315, CM143544; called by muse, mutect2, varscan2
- TERT | c.2086C>T p.R696C | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs973201915, COSV57206668; called by muse, mutect2, varscan2
- TRIM55 | c.1524+2T>C p.X508_splice | Splice Site (SNP) | VAF 3/13 reads (23%) | catalogued as COSV99396569; called by muse, mutect2
- ZNF443 | c.1513G>T p.E505* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as rs1165952586; called by muse, varscan2
- ADAMTSL1 | c.1939C>G p.L647V | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- ARAP2 | c.125A>G p.N42S | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- ATR | c.7675C>A p.H2559N | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2
- BBS9 | c.1891G>A p.D631N (on ENST00000242067 / NM_001348036.1; = p.D591N on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- C8orf82 | c.231C>G p.F77L | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DBR1 | c.516G>T p.L172F | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- EEF2 | c.700G>T p.A234S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- ENTHD1 | c.1463T>C p.L488P | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.023); called by muse, mutect2
- HCAR3 | c.20A>G p.Q7R | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HYAL2 | c.77C>T p.T26I | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- IGHV1-69 | c.293C>A p.A98D | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- ISYNA1 | c.1147A>T p.I383F | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- LRRN3 | c.249A>T p.K83N | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- MED13L | c.3025G>T p.D1009Y | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- MME | c.2071G>T p.A691S | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- OR8H3 | c.138G>T p.M46I | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- PKD2L2 | c.476C>T p.T159I | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- PPP1R1A | c.449A>G p.E150G | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RBM26 | c.1901A>T p.Q634L (on ENST00000438737 / NM_001366735.2; = p.Q631L on NM_022118.5) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.787); called by muse, mutect2
- RICTOR | c.5027T>G p.L1676* | Nonsense Mutation (SNP) | VAF 9/59 reads (15%) | called by muse, mutect2, varscan2
- S100A8 | c.110T>C p.L37S | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SGO2 | c.2164A>T p.I722L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- ST6GALNAC5 | c.58A>G p.T20A | Missense Mutation (SNP) | VAF 35/55 reads (64%) | PolyPhen benign (0.034); called by muse, mutect2, varscan2
- STX10 | c.607G>T p.D203Y | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TMEM131 | c.2614dup p.S872Ffs*9 | Frame Shift Ins (INS) | VAF 13/46 reads (28%) | called by mutect2, pindel, varscan2
- TNXB | c.11228C>A p.A3743D (on ENST00000647633; = p.A3496D on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRIM25 | c.1009A>T p.I337F | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- UBA3 | c.1040A>T p.D347V | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- UNC13A | c.1776C>A p.H592Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USP43 | c.2671C>T p.P891S | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2
- ZNF644 | c.397A>G p.K133E | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACBD4 | c.771C>T p.P257= (on ENST00000376955 / NM_001378111.1; = p.P261S on NM_024722.4) | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as rs1293859188; called by muse, mutect2, varscan2
- CEACAM5 | c.1149C>T p.V383= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as rs528850947; called by muse, mutect2, varscan2
- CFAP65 | c.2247C>T p.C749= | Silent (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2, varscan2
- COX10 | c.651C>T p.N217= | Silent (SNP) | VAF 11/35 reads (31%) | called by muse, mutect2, varscan2
- PYGB | c.6G>T p.A2= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV53820294; called by muse, mutect2, varscan2
- SI | c.5229A>G p.V1743= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs547324596; called by muse, mutect2, varscan2
- SI | c.4950C>T p.Y1650= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs370336977, COSV52274232; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TNXB | c.11229C>G p.A3743= (on ENST00000647633; = p.A3496= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV100926785; called by muse, mutect2, varscan2
- ZMYND19 | c.147T>A p.A49= | Silent (SNP) | VAF 16/52 reads (31%) | called by muse, mutect2, varscan2
- ZNF254 | c.1428C>A p.T476= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as rs760834419, COSV61644777; called by muse, varscan2
- ZNF3 | c.156C>T p.T52= | Silent (SNP) | VAF 5/15 reads (33%) | called by mutect2, varscan2
- OR2W5 | n.1081C>T | RNA (SNP) | VAF 10/32 reads (31%) | catalogued as rs1191921872; called by muse, mutect2, varscan2
- SMTN | c.1632+1683C>A | Intron (SNP) | VAF 6/30 reads (20%) | catalogued as COSV60781749; called by muse, mutect2, varscan2
